Gene-level copy-number profile of tumor specimen TCGA-69-7978-01A from TCGA case TCGA-69-7978, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.6 years (21,785 days).
Specimen TCGA-69-7978-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7eb76a57-6387-4114-95f2-1d0e6042f7fc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-7978-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/02d15f7c-b47f-4a62-a778-d0b9240e1228

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 19,605; copy number 3: 17,533; copy number 4: 15,441; copy number 5: 3,941; copy number 6: 3,034; copy number 7: 144; copy number 8: 31; copy number 14: 87; copy number 20: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-69-7978-01A-11D-2183-01): tumor purity 0.2, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 265 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:109,409,990–109,723,273, 1 gene, copy number 7 (within-gene range 6–7): LINC01205.
- chr3:109,602,828–112,649,530, 41 genes, copy number 7: MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3, CD96, AC092916.1, ATP6V0CP2, AC092916.2, ZBED2, NT5C3AP2, PLCXD2, PLCXD2-AS1, PHLDB2, AC117509.1, ABHD10, TAGLN3, RFKP2, TMPRSS7, C3orf52, MIR567, GCSAM, TBILA, SLC9C1, AC128688.1, AC112487.1, AC112487.2, CD200, AC092894.1, BTLA, OR7E100P, AC092692.1, ATG3, SLC35A5, CCDC80.
- chr3:165,772,904–168,095,924, 31 genes, copy number 8: BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1.
- chr3:193,241,128–193,844,024, 14 genes, copy number 7: PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, AC069421.2, AC069421.3, LINC02038.
- chr7:52,165,235–52,503,434, 3 genes, copy number 20: AC079763.1, AC006320.1, AC006459.1.
- chr18:47,390–515,294, 13 genes, copy number 7: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925.
- chr19:29,775,504–30,713,538, 16 genes, copy number 7 (within-gene range 2–7): AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1.
- chr19:53,909,335–55,645,623, 146 genes, copy number 7–14 (within-gene range 2–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
